Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A7SB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A7SB-01A (Primary Tumor).

[page 1 of 3]
A. Liver, posterior segmentectomy:

.HEPATOCELLULAR CARCINOMA with focal sarcomatous differentiation

Tumor number: two

0% Sarcomatous, per TSS. BCR.

Satellite nodule: no

Location : S6, S7

Gross type: vaguely nodular(S7) and nodular with perinodular extension (S6)

Size(cm): 2.5x2.5x2.4cm (S6) and 1.5x1.5x1.4cm (S7)

Differentiation: The worst differentiation: Edmondson grade IV

The major differentiation: Edmondson grade II

Histologic type: microtrabecular and pseudoglandular

Cell type: Hepatic and Spindle

Tumor necrosis : no

Hemorrhage : no

Fatty change : no

Fibrous capsule : 1) complete (S6), 2) No capsule(S7)

Infiltration of capsule : yes

Septum formation : yes

Surgical margin invasion : no(margin of the clearance: 0.5mm at "S7" mass)

Serosa invasion: no

Portal vein invasion : no

Bile duct invasion : no

Hepatic vein invasion : no

Hepatic artery invasion : no

Microvessel invasion : no

Intrahepatic metastasis : no

Multicentric occurrence : yes

T stage : pT2

ICD-O-3

Carcinoma, hepatocellular NOS

8170/3

Site Liver C22.0

Q4 10/4/13

.Non-tumor liver

Chronic hepatitis : yes

Etiology : HBV

Grade, lobular : minimal

Grade, portoperiportal : none

Stage(fibrosis) : no

Cirrhosis : no

Dysplastic nodule : no

Ductal epithelial dysplasia : no

Other liver disease : Fatty change, macrovesicular (about 10%)

[page 2 of 3]
B. Falciform ligament, excision:
. No pathologic abnormality

C. Gallbladder, cholecystectomy:
. Cholesterol polyps

D. Tissue labeled as "LN" , biopsy:
. Fibroadipose tissue only

< Result of immunohistochemical stain>

- . Hepatocyte (block A3 and A5): Positive in tumor cells
- . Cytokeratin 19 (block A3 and A5): Negative in tumor cells
- . Cytokeratin 7 (block A3 and A5): Focal positive in tumor cells.
- . Cytokeratin 7 (block A7): Bile duct positive
- . Vimetin (block A3): Focal positive
- . Cam5.2 (block A3): Positive

< Result of special stain, block A7 >
. Iron: Negative

A. The specimen received in formalin is a product of segmentectomy of liver, measuring 16.5x8x4.5cm and weighing 230gm. The capsular surface and parenchymal resection margin are clear. On serial sections, there is a multinodular confluent expanding nodular type mass, measuring 2.5x2.5x2.4cm. The mass abuts capsule and the cut surface is whitish solid. Also noted is a well defined greenish mass, measuring 1.5x1.5x1.4cm. The mass is abutting capsule and is 0.1cm apart from parenchymal resection margin. This mass is 3cm apart from the larger mass. Remaining parenchyma is unremarkable. Representative sections are embedded in 7 cassettes. (A1and2-larger mass one plane, A3and4-larger mass one plane, A5-small mass one plane, A6-small mass one plane, A7-normal liver)

B. The specimen received in formalin is a lump of adipose tissue, clinically labeled as "falciform ligament" , measuring 12x3x1.5cm. On serial section, there is no definite mass. Representative sections are embedded in one cassette.

C. The specimen received in formalin is a gallbladder, measuring 7x2.5x2.5cm. The external surface is unremarkable. On opening, there is a black stone, measuring 0.8cm in diameter. The mucosa is greenish velvety appearance with

[page 3 of 3]
2

several tiny yellowish polyps, measuring up to 0.1cm. The wall measures 0.2cm in thickness. Representative sections are embedded in one cassette.

D. The specimen received in formalin is a compartmentalized lymph node. Entirely embedded in one cassette.

H&E(10), MT(1), RTC(1), D-PAS(1), Iron(1), Cytokeratin 7(3), Hepatocyte (2), Cytokeratin 19 (2), Vimetin (1), Cam5.2(1)

Source: NCI Genomic Data Commons file 7402b068-c845-40cb-8b4b-f1d9d2c0b98b (TCGA-RC-A7SB.5B9D93C9-3051-4E0C-97B1-25E9CDD9CFE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).